Somatic mutation profile of tumor specimen TCGA-HT-8108-01A (aliquot TCGA-HT-8108-01A-11D-2395-08) from TCGA case TCGA-HT-8108, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 26.1 years (9,539 days).
Specimen TCGA-HT-8108-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7af844b7-f96c-44df-8fb5-1ad441bad5b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-8108-10A (Blood Derived Normal), aliquot TCGA-HT-8108-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d114b763-9d79-46fc-8557-456b3b291dd0

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 13, Silent 5, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 34/85 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- BBS7 | c.1433C>A p.P478H | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52657190; called by muse, mutect2, varscan2
- CADM1 | c.302A>G p.N101S | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.18); catalogued as COSV59013407; called by muse, mutect2, varscan2
- CDK10 | c.151G>A p.G51S | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs938780672, COSV58415001; called by muse, mutect2, varscan2
- EIF4A2 | c.7G>T p.G3C | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.219); catalogued as COSV60625271; called by muse, mutect2, varscan2
- IL18 | c.540G>T p.L180F | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0.026); catalogued as COSV54781831; called by muse, mutect2, varscan2
- IRS4 | c.532G>C p.A178P | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64534278; called by muse, mutect2, varscan2
- KERA | c.962A>G p.H321R | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57130879; called by muse, mutect2, varscan2
- OPHN1 | c.1111C>G p.H371D | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.655); catalogued as COSV62783089; called by muse, mutect2, varscan2
- RENBP | c.476A>C p.E159A | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.047); catalogued as COSV60073489; called by muse, varscan2
- SYNE1 | c.23704G>A p.A7902T (on ENST00000367255 / NM_182961.4; = p.A7831T on NM_033071.3) | Missense Mutation (SNP) | VAF 61/91 reads (67%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as rs372990463; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.459del p.G154Afs*16 | Frame Shift Del (DEL) | VAF 61/110 reads (55%) | catalogued as COSV52700360, COSV52751929; called by mutect2, pindel, varscan2
- TTN | c.18439G>A p.G6147R (on ENST00000591111; = p.G5220R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | PolyPhen probably damaging (0.944); catalogued as rs755082868, COSV60128494; called by muse, mutect2, varscan2
- ATRX | c.6557_6558dup p.F2187Lfs*16 | Frame Shift Ins (INS) | VAF 50/153 reads (33%) | called by mutect2, pindel, varscan2
- SPANXB1 | c.302C>A p.P101H | Missense Mutation (SNP) | VAF 38/477 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); called by muse, mutect2
- GNAL | c.1011G>A p.T337= (on ENST00000269162 / NM_001142339.3; = p.T414= on NM_182978.4) | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as rs746050895, COSV52328701; called by muse, mutect2, varscan2
- LRRC43 | c.1458G>A p.L486= | Silent (SNP) | VAF 6/136 reads (4%) | catalogued as COSV60290579; called by muse, mutect2
- MS4A3 | c.276G>A p.P92= | Silent (SNP) | VAF 52/113 reads (46%) | catalogued as rs376718907; called by muse, mutect2, varscan2
- ROPN1L | c.474C>T p.G158= | Silent (SNP) | VAF 59/156 reads (38%) | catalogued as rs539286998, COSV56873989; called by muse, mutect2, varscan2
- SIM1 | c.27G>A p.A9= | Silent (SNP) | VAF 28/187 reads (15%) | catalogued as rs747311520, COSV53489112; called by muse, mutect2, varscan2
